Somatic mutation profile of tumor specimen TCGA-12-1088-01A (aliquot TCGA-12-1088-01A-01W-0611-08) from TCGA case TCGA-12-1088, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.8 years (19,667 days).
Specimen TCGA-12-1088-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4f9482c-c3cc-4a18-b27b-6b12705c38d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-1088-10C (Blood Derived Normal), aliquot TCGA-12-1088-10C-01W-0611-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5287d32b-dccd-4e98-8bd8-cfb2db0e1149

The open-access MAF lists 62 somatic variants for this specimen: 48 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 12, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 108/158 reads (68%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS16 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.13); catalogued as rs558198391, COSV56988858; called by muse, mutect2, varscan2
- AP000721.1 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.885); catalogued as rs772015686, COSV100029279; called by muse, mutect2, varscan2
- ATP6V0A4 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs539497353, COSV59475611; called by muse, mutect2, varscan2
- C3AR1 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 37/771 reads (5%) | catalogued as COSV99368039, COSV99368386; called by muse, mutect2
- CCDC141 | c.3887C>A p.A1296D | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV99836574; called by muse, mutect2
- CCNH | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99169723; called by muse, mutect2, varscan2
- CCR9 | c.184G>T p.G62C (on ENST00000357632 / NM_031200.3; = p.G50C on NM_006641.4) | Missense Mutation (SNP) | VAF 363/561 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100591656; called by muse, mutect2, varscan2
- CELSR3 | c.3469G>A p.V1157I | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs549604301, COSV50941783; called by muse, mutect2, varscan2
- CFAP47 | c.2557T>C p.S853P | Missense Mutation (SNP) | VAF 193/646 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV99934827; called by muse, mutect2, varscan2
- CNKSR3 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 329/855 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385793306, COSV101401337, COSV70481215; called by muse, mutect2, varscan2
- COL6A3 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 46/134 reads (34%) | catalogued as rs549047014, COSV55118771; called by muse, mutect2, varscan2
- DENND1A | c.1805T>C p.L602P | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.132); catalogued as COSV101011920; called by muse, mutect2, varscan2
- DFFA | c.387G>T p.R129S | Missense Mutation (SNP) | VAF 36/458 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV100986635; called by muse, mutect2
- EPHA7 | c.1742+1G>T p.X581_splice | Splice Site (SNP) | VAF 24/61 reads (39%) | catalogued as COSV65183461; called by muse, mutect2, varscan2
- ERC2 | c.2641A>G p.K881E | Missense Mutation (SNP) | VAF 45/1354 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99883237; called by muse, mutect2
- FHL1 | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); catalogued as COSV100600742; called by muse, mutect2
- FRMPD4 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV101042618, COSV66221586; called by muse, mutect2
- GABRA6 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV50877577, COSV50900675; called by muse, mutect2, varscan2
- GDF9 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs775301872, COSV51526052, COSV51526059; called by muse, mutect2, varscan2
- GJB2 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as CM050056, COSV101241482; called by muse, mutect2
- KCNJ5 | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100610629; called by muse, mutect2, varscan2
- KHDRBS2 | c.187A>T p.R63* | Nonsense Mutation (SNP) | VAF 18/115 reads (16%) | catalogued as COSV99832750; called by muse, mutect2, varscan2
- KIAA1217 | c.2293G>T p.V765L | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.255); catalogued as COSV100286430; called by muse, mutect2, varscan2
- LHFPL1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767818059, COSV64332935; called by muse, mutect2, varscan2
- MAGEC1 | c.2396A>C p.Q799P | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as COSV99595388; called by mutect2, varscan2
- MED12L | c.5984A>G p.Y1995C | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as COSV99852492; called by muse, mutect2, varscan2
- OR4C6 | c.325G>T p.G109W | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100051547, COSV58603820; called by muse, mutect2, varscan2
- PCDHAC2 | c.2271C>A p.Y757* | Nonsense Mutation (SNP) | VAF 16/182 reads (9%) | catalogued as COSV99145774; called by muse, mutect2
- PGRMC1 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.482); catalogued as COSV99483515; called by muse, mutect2, varscan2
- PHF3 | c.2196G>T p.M732I | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100013157; called by muse, mutect2, varscan2
- PIK3AP1 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100225679; called by muse, mutect2
- PLG | c.1531C>T p.H511Y | Missense Mutation (SNP) | VAF 30/572 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99804527; called by muse, mutect2
- RPS6KA3 | c.691A>C p.T231P | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101084273; called by muse, mutect2
- SIGLEC7 | c.780C>G p.N260K | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs772659773, COSV99978611; called by muse, mutect2, varscan2
- SLC22A13 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs17857080, COSV100314532; called by muse, mutect2, varscan2
- SRPX2 | c.1314G>T p.E438D | Missense Mutation (SNP) | VAF 24/866 reads (3%) | SIFT tolerated (0.63); PolyPhen benign (0.028); catalogued as COSV99342807; called by muse, mutect2
- ST8SIA6 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as rs759505751, COSV101112121; called by muse, mutect2, varscan2
- TMEM106B | c.281+1G>A p.X94_splice | Splice Site (SNP) | VAF 65/314 reads (21%) | catalogued as rs751818729, COSV67543354; called by muse, mutect2, varscan2
- TRIM69 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 9/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100274234; called by muse, mutect2
- TSPAN12 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99763111; called by muse, mutect2
- TTN | c.97817G>A p.R32606K (on ENST00000591111; = p.R25182K on NM_003319.4) | Missense Mutation (SNP) | VAF 471/1097 reads (43%) | PolyPhen possibly damaging (0.513); catalogued as COSV100599263, COSV100604958; called by muse, mutect2, varscan2
- ZNF564 | c.125G>T p.C42F | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV100213074; called by muse, mutect2, varscan2
- ZNF816 | c.1004A>C p.H335P | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99554528; called by muse, mutect2, varscan2
- BBS12 | c.1432_1433del p.P478Ffs*6 | Frame Shift Del (DEL) | VAF 58/221 reads (26%) | called by mutect2, pindel, varscan2
- CHMP2B | c.15C>G p.F5L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- KIR3DL3 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 155/399 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- SPRED2 | c.773del p.E258Gfs*19 | Frame Shift Del (DEL) | VAF 26/137 reads (19%) | called by mutect2, pindel, varscan2
- ACAD9 | c.621C>A p.L207= | Silent (SNP) | VAF 8/210 reads (4%) | catalogued as COSV100459093; called by muse, mutect2
- AFF2 | c.879T>C p.D293= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV100649662; called by muse, mutect2
- CYP4F3 | c.1521C>T p.R507= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs745845603; called by mutect2, varscan2
- FREM2 | c.7890G>A p.L2630= | Silent (SNP) | VAF 8/156 reads (5%) | catalogued as COSV99748180; called by muse, mutect2
- GRIA1 | c.2361C>T p.C787= | Silent (SNP) | VAF 17/186 reads (9%) | catalogued as rs755459632, COSV53598399, COSV53629481; called by muse, mutect2
- MAMLD1 | c.2010T>G p.P670= | Silent (SNP) | VAF 30/346 reads (9%) | catalogued as COSV99475785; called by muse, mutect2
- MBOAT7 | c.84G>T p.G28= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99824749; called by muse, mutect2
- PHKA2 | c.3615G>A p.P1205= | Silent (SNP) | VAF 46/183 reads (25%) | catalogued as rs200550207, COSV101176933; ClinVar: likely benign; called by muse, varscan2
- PRICKLE3 | c.1782G>A p.S594= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs199610034, COSV100889908; called by muse, mutect2, varscan2
- TCEAL3 | c.363C>T p.S121= | Silent (SNP) | VAF 59/556 reads (11%) | catalogued as COSV99685249; called by muse, mutect2, varscan2
- TNFRSF9 | c.489C>T p.A163= | Silent (SNP) | VAF 12/204 reads (6%) | catalogued as rs780480575, COSV66349201; called by muse, mutect2
- XPNPEP1 | c.1446C>T p.Y482= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs778274041, COSV100450826; called by muse, mutect2, varscan2
- DENND10P1 | n.433C>G | RNA (SNP) | VAF 30/192 reads (16%) | called by muse, mutect2, varscan2
- SORBS1 | c.3640-734G>A | Intron (SNP) | VAF 79/147 reads (54%) | catalogued as COSV99527771; called by muse, mutect2, varscan2
